Somatic mutation profile of tumor specimen TCGA-63-A5MW-01A (aliquot TCGA-63-A5MW-01A-11D-A26M-08) from TCGA case TCGA-63-A5MW, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB.
Specimen TCGA-63-A5MW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62d33933-5f37-41ee-b5a7-409f6f8aaec7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-63-A5MW-10A (Blood Derived Normal), aliquot TCGA-63-A5MW-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7264650f-36ba-4681-8571-9aea5c48128d

The open-access MAF lists 497 somatic variants for this specimen: 383 protein-altering or splice-affecting, 106 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 333, Silent 106, Nonsense Mutation 23, Frame Shift Del 11, RNA 5, Splice Site 5, Splice Region 4, Frame Shift Ins 4, 3'UTR 1, Translation Start Site 1, Nonstop Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 56/91 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587781504, COSV52708806, COSV52766179, COSV52793434; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AAK1 | c.900A>T p.K300N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV101276031; called by muse, mutect2, varscan2
- ABCB11 | c.2600A>T p.Q867L | Missense Mutation (SNP) | VAF 91/198 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV99792871; called by muse, mutect2, varscan2
- ABCB7 | c.1638G>C p.R546S (on ENST00000373394 / NM_001271696.3; = p.R547S on NM_004299.6) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as COSV99504750; called by muse, mutect2, varscan2
- ABCC9 | c.2188C>T p.H730Y | Missense Mutation (SNP) | VAF 113/228 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53975580; called by muse, mutect2, varscan2
- ADAM28 | c.1823A>T p.D608V | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1360013581, COSV99739697; called by muse, mutect2, varscan2
- ADAMTS12 | c.4561C>T p.P1521S | Missense Mutation (SNP) | VAF 10/266 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as COSV61256925, COSV61257064; called by muse, mutect2
- ADAMTSL3 | c.2144G>A p.C715Y | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99720860; called by muse, mutect2
- ADCY6 | c.662C>A p.A221E | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.215); catalogued as COSV100326866; called by muse, mutect2, varscan2
- ADGRB3 | c.4348A>T p.R1450* | Nonsense Mutation (SNP) | VAF 11/56 reads (20%) | catalogued as COSV99486425; called by muse, mutect2, varscan2
- AGAP1 | c.112G>T p.E38* | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | catalogued as COSV100366924; called by muse, mutect2, varscan2
- AHCTF1 | c.6331G>C p.E2111Q (on ENST00000366508; = p.E2085Q on NM_015446.5) | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs1300898116, COSV100404342; called by muse, mutect2, varscan2
- AIRE | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.34); catalogued as rs1451239285, COSV99381382; called by muse, mutect2, varscan2
- AKR7A2 | c.233G>T p.S78I | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.186); catalogued as COSV99352164; called by muse, mutect2
- ALB | c.523G>T p.A175S | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.227); catalogued as COSV99892095; called by mutect2, varscan2
- ALDH16A1 | c.2247G>A p.Q749= | Splice Region (SNP) | VAF 59/151 reads (39%) | catalogued as rs1407026661, COSV99513183; called by muse, mutect2, varscan2
- ALG10B | c.140G>C p.R47P | Missense Mutation (SNP) | VAF 88/209 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as COSV100439984; called by muse, mutect2, varscan2
- ALMS1 | c.1555C>A p.Q519K | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.889); catalogued as COSV100043470; called by muse, mutect2, varscan2
- ALMS1 | c.5306A>C p.Y1769S | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as COSV100043472; called by muse, mutect2, varscan2
- ANKS1B | c.788T>C p.L263S | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100247513; called by muse, mutect2, varscan2
- ANPEP | c.2407C>T p.Q803* | Nonsense Mutation (SNP) | VAF 55/159 reads (35%) | catalogued as COSV100263466; called by muse, mutect2, varscan2
- AP002512.3 | c.14C>A p.T5N | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0.02); catalogued as COSV100392670; called by muse, mutect2, varscan2
- ARFGAP1 | c.906G>T p.L302F | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1312567474, COSV100796718; called by muse, mutect2, varscan2
- ARHGAP27 | c.2493-1G>C p.X831_splice (on ENST00000428638 / NM_001282290.1; = p.X490_splice on NM_199282.3) | Splice Site (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100976609; called by muse, mutect2
- ARHGAP45 | c.1990G>T p.G664* | Nonsense Mutation (SNP) | VAF 8/107 reads (7%) | catalogued as COSV100491063; called by muse, mutect2
- ARHGEF17 | c.5996G>A p.G1999D | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.147); catalogued as COSV99736631; called by muse, mutect2
- ARID1A | c.5488A>C p.K1830Q | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV100253161; called by muse, mutect2, varscan2
- ARSG | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.722); catalogued as COSV101477921; called by muse, mutect2, varscan2
- ASIC4 | c.1513C>A p.H505N (on ENST00000347842 / NM_182847.3; = p.H524N on NM_018674.6) | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV99705271; called by muse, mutect2
- ASPSCR1 | c.427G>T p.D143Y | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV100145003; called by muse, mutect2, varscan2
- ASTN1 | c.3340C>A p.L1114M | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV100707626; called by muse, mutect2, varscan2
- ATR | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.058); catalogued as COSV100638538; called by muse, mutect2, varscan2
- BAG2 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 13/156 reads (8%) | catalogued as COSV100443868; called by muse, mutect2
- BIN2 | c.97G>T p.G33W | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99909685; called by muse, mutect2, varscan2
- BRD7 | c.1315C>T p.L439F | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.875); catalogued as COSV101165045; called by muse, mutect2, varscan2
- BVES | c.482A>T p.Y161F | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100115092, COSV58947214; called by muse, mutect2, varscan2
- C17orf75 | c.475G>C p.E159Q | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV99858780; called by muse, mutect2, varscan2
- C20orf194 | c.1595A>T p.D532V | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV99331410; called by muse, mutect2, varscan2
- C4orf50 | c.269G>T p.R90L (on ENST00000324058; = p.R1322L on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.019); catalogued as COSV100136140; called by muse, mutect2, varscan2
- C6orf15 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs1195576380, COSV99457205; called by muse, mutect2
- CADM2 | c.184C>A p.Q62K (on ENST00000407528 / NM_001167674.2; = p.Q64K on NM_153184.4) | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as COSV101059118; called by muse, mutect2
- CAMKV | c.461A>G p.Y154C | Missense Mutation (SNP) | VAF 60/113 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99615932; called by muse, mutect2, varscan2
- CASP7 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.86); catalogued as rs115389257; called by muse, mutect2, varscan2
- CATSPERE | c.1090A>T p.I364F | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.187); catalogued as COSV100835337; called by muse, mutect2, varscan2
- CCDC141 | c.3760G>T p.G1254W | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as COSV99837375; called by muse, mutect2, varscan2
- CCM2L | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as rs1568910274, COSV99395434; called by muse, mutect2, varscan2
- CD1C | c.627G>C p.W209C | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs761591081, COSV100939444; called by muse, mutect2, varscan2
- CD207 | c.609G>C p.K203N | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs192177291, COSV101338590; called by muse, mutect2
- CDC5L | c.718A>G p.R240G | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs1351016031, COSV101015169; called by muse, mutect2, varscan2
- CDH10 | c.1040A>T p.K347I | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as COSV100052906; called by muse, mutect2, varscan2
- CDH18 | c.2345G>T p.G782V | Missense Mutation (SNP) | VAF 27/280 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99932660; called by muse, mutect2
- CDH5 | c.925G>C p.E309Q | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.213); catalogued as COSV100439413; called by muse, mutect2, varscan2
- CDH9 | c.376C>A p.L126I | Missense Mutation (SNP) | VAF 377/472 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99151493; called by muse, mutect2, varscan2
- CEP85 | c.553G>T p.E185* | Nonsense Mutation (SNP) | VAF 29/134 reads (22%) | catalogued as COSV53331624; called by muse, mutect2, varscan2
- CFHR3 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV100807744; called by muse, mutect2
- CFHR4 | c.1460A>G p.Q487R (on ENST00000367416 / NM_001201551.2; = p.Q241R on NM_006684.5) | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.527); catalogued as COSV99261258; called by muse, mutect2, varscan2
- CHFR | c.346G>T p.V116L | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.406); catalogued as COSV99905678; called by muse, mutect2, varscan2
- CHMP2B | c.600T>A p.D200E | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as COSV99773657; called by muse, mutect2
- CHMP3 | c.634G>C p.A212P | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.332); catalogued as COSV99806810; called by muse, mutect2, varscan2
- CLIP2 | c.712G>T p.V238L | Missense Mutation (SNP) | VAF 108/203 reads (53%) | SIFT tolerated (1); PolyPhen possibly damaging (0.474); catalogued as COSV56281220, COSV99792155; called by muse, mutect2, varscan2
- CLPTM1L | c.368A>C p.Q123P | Missense Mutation (SNP) | VAF 27/366 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.46); catalogued as COSV100307313; called by muse, mutect2
- CLVS2 | c.127G>T p.D43Y | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99253456; called by muse, varscan2
- CLVS2 | c.142C>A p.R48S | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.56); catalogued as COSV99253461, COSV99253683; called by muse, varscan2
- CNTN3 | c.2884C>A p.L962I | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99725882; called by muse, mutect2
- CNTN4 | c.878A>G p.Y293C | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370616204; called by muse, mutect2, varscan2
- CNTNAP4 | c.196G>C p.G66R | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100273013, COSV56697064; called by muse, mutect2, varscan2
- CNTNAP4 | c.2628G>C p.W876C | Missense Mutation (SNP) | VAF 48/203 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100273018; called by muse, mutect2, varscan2
- COL17A1 | c.3463G>A p.G1155S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100793327; called by muse, mutect2, varscan2
- COL27A1 | c.5008A>T p.S1670C | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100621288; called by muse, mutect2, varscan2
- COL4A4 | c.4556C>A p.T1519K | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100307582, COSV61630972; called by muse, mutect2
- COL5A2 | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV100880715; called by muse, mutect2, varscan2
- COL6A3 | c.3872G>C p.S1291T | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.98); PolyPhen benign (0.022); catalogued as COSV99800898; called by muse, mutect2, varscan2
- COMMD1 | c.508C>A p.Q170K | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.294); catalogued as COSV100312957; called by muse, mutect2, varscan2
- CPED1 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV100121415; called by muse, mutect2, varscan2
- CPQ | c.278A>G p.Q93R | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99614350; called by muse, mutect2, varscan2
- CSMD3 | c.5249G>T p.G1750V (on ENST00000297405 / NM_001363185.1; = p.G1646V on NM_052900.3) | Missense Mutation (SNP) | VAF 95/163 reads (58%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.944); catalogued as COSV99845885; called by muse, mutect2, varscan2
- CTAGE1 | c.1181C>G p.A394G | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as COSV101194664; called by muse, mutect2, varscan2
- DAB1 | c.1564C>A p.Q522K (on ENST00000371231; = p.Q489K on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.036); catalogued as COSV100976584; called by muse, mutect2, varscan2
- DAPK2 | c.42C>G p.F14L | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.615); catalogued as COSV99977713; called by muse, mutect2, varscan2
- DBX1 | c.436T>C p.F146L | Missense Mutation (SNP) | VAF 68/244 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as COSV99910306; called by muse, mutect2, varscan2
- DCAF4L2 | c.958G>T p.V320L | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100150678, COSV60478239; called by muse, mutect2, varscan2
- DDAH2 | c.731A>G p.N244S | Missense Mutation (SNP) | VAF 41/329 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.403); catalogued as COSV101007550; called by muse, mutect2, varscan2
- DEFB127 | c.214C>A p.P72T | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101213885; called by muse, mutect2, varscan2
- DEPDC7 | c.148G>T p.V50L (on ENST00000241051 / NM_001077242.2; = p.V41L on NM_139160.2) | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99572886; called by muse, mutect2
- DIP2A | c.2177C>A p.A726D | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV100596284; called by muse, mutect2, varscan2
- DLG5 | c.3179C>T p.P1060L | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs1228983498, COSV100967826, COSV64948380; called by muse, mutect2, varscan2
- DLGAP3 | c.1180A>T p.S394C | Missense Mutation (SNP) | VAF 107/293 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99333111; called by muse, mutect2, varscan2
- DLL1 | c.1032G>A p.T344= | Splice Region (SNP) | VAF 5/72 reads (7%) | catalogued as COSV64538110; called by muse, mutect2
- DNAH1 | c.5941G>T p.E1981* | Nonsense Mutation (SNP) | VAF 31/95 reads (33%) | catalogued as COSV101326918; called by muse, mutect2, varscan2
- DOCK5 | c.1614A>C p.E538D | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.312); catalogued as COSV99377711; called by muse, mutect2
- DOCK9 | c.4047G>T p.K1349N (on ENST00000376460 / NM_001366676.2; = p.K1350N on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100240805; called by muse, varscan2
- DPM1 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.031); catalogued as COSV99724486; called by muse, mutect2, varscan2
- DUSP11 | c.687C>A p.F229L | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55594655, COSV99731221; called by muse, mutect2
- DYNC2H1 | c.11570A>G p.N3857S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100519576; called by mutect2, varscan2
- ECT2 | c.1258T>G p.S420A (on ENST00000392692 / NM_001349098.2; = p.S389A on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.622); catalogued as rs767708975, COSV99221797; called by muse, mutect2, varscan2
- ECT2 | c.1259C>T p.S420F (on ENST00000392692 / NM_001349098.2; = p.S389F on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99221800; called by muse, mutect2, varscan2
- EFHC1 | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as COSV100932131; called by muse, mutect2
- EFL1 | c.2197C>G p.Q733E | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV99188333; called by muse, mutect2, varscan2
- ENPP1 | c.1762C>T p.H588Y | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100719633; called by muse, mutect2, varscan2
- EPB41L3 | c.2209G>T p.E737* | Nonsense Mutation (SNP) | VAF 18/157 reads (11%) | catalogued as COSV100547950, COSV59451466; called by muse, mutect2, varscan2
- ERBB4 | c.1690G>C p.D564H | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as COSV53563829, COSV99631512; called by muse, mutect2, varscan2
- EVI2B | c.800C>T p.T267I | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as COSV100445632; called by muse, mutect2, varscan2
- EVX1 | c.485G>C p.S162T | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.196); catalogued as COSV99764051; called by muse, mutect2, varscan2
- FAM117B | c.854A>C p.K285T | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100287871; called by muse, mutect2, varscan2
- FAM174A | c.187G>T p.A63S | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.779); catalogued as COSV100444586; called by muse, mutect2, varscan2
- FAM83H | c.662G>C p.G221A | Missense Mutation (SNP) | VAF 41/374 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101187071; called by muse, mutect2, varscan2
- FARP2 | c.919A>T p.K307* | Nonsense Mutation (SNP) | VAF 57/107 reads (53%) | catalogued as COSV99885405; called by muse, mutect2, varscan2
- FBXL14 | c.400A>G p.S134G | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.899); catalogued as COSV100201612; called by muse, mutect2
- FBXO24 | c.1553C>A p.A518D (on ENST00000241071 / NM_033506.3; = p.A556D on NM_012172.5) | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV99575623; called by muse, mutect2
- FBXO39 | c.89G>A p.W30* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as COSV100386256; called by muse, mutect2, varscan2
- FBXO42 | c.1889A>G p.N630S | Missense Mutation (SNP) | VAF 73/257 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); catalogued as COSV100981902; called by muse, mutect2, varscan2
- FETUB | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 140/390 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV54004890, COSV99409130; called by muse, mutect2, varscan2
- FLG | c.2185C>A p.Q729K | Missense Mutation (SNP) | VAF 158/659 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.347); catalogued as rs545979921, COSV100912052; called by muse, mutect2, varscan2
- FMO4 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 56/247 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100882159; called by muse, mutect2, varscan2
- FNDC1 | c.5627C>T p.T1876I | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1275764095, COSV99796583; called by muse, mutect2, varscan2
- FOXG1 | c.844del p.A282Pfs*44 | Frame Shift Del (DEL) | VAF 41/100 reads (41%) | catalogued as COSV57399395; called by mutect2, pindel, varscan2
- FRMD1 | c.589C>A p.H197N | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as COSV99350084; called by muse, mutect2, varscan2
- FSIP2 | c.20557A>C p.S6853R | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.369); catalogued as COSV100556203; called by muse, mutect2, varscan2
- G3BP1 | c.254C>T p.T85M | Missense Mutation (SNP) | VAF 47/73 reads (64%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as rs773786985, COSV100664038; called by muse, mutect2, varscan2
- GABPB1 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.086); catalogued as rs986519244, COSV55014615; called by muse, mutect2, varscan2
- GALNT17 | c.888C>A p.S296R | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV100355923; called by muse, mutect2, varscan2
- GDPD3 | c.573C>T p.A191= | Splice Region (SNP) | VAF 13/85 reads (15%) | catalogued as rs200801803, COSV53773211; called by muse, mutect2, varscan2
- GPANK1 | c.367C>A p.L123M | Missense Mutation (SNP) | VAF 66/139 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100789047; called by muse, mutect2
- GPR137C | c.937G>T p.V313L | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100397890; called by muse, mutect2, varscan2
- GPR6 | c.513T>A p.Y171* | Nonsense Mutation (SNP) | VAF 9/118 reads (8%) | catalogued as COSV99254522; called by muse, mutect2
- GPRC6A | c.1336-2A>C p.X446_splice | Splice Site (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100114711, COSV59953244; called by muse, mutect2
- GPS1 | c.114G>C p.E38D | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as COSV100136119; called by muse, mutect2, varscan2
- GRID2 | c.1978C>A p.R660S | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs781013535, COSV99945894; called by muse, mutect2, varscan2
- GRIN2A | c.3937C>G p.L1313V | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs375287911, COSV58060010; called by muse, mutect2, varscan2
- GRK1 | c.844G>T p.V282L | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.087); catalogued as COSV100175448, COSV59552976; called by muse, mutect2, varscan2
- GRK4 | c.741+1G>T p.X247_splice (on ENST00000398052 / NM_182982.3; = p.X215_splice on NM_005307.3) | Splice Site (SNP) | VAF 11/70 reads (16%) | catalogued as COSV100584258; called by muse, mutect2, varscan2
- GRM5 | c.2179C>T p.R727* | Nonsense Mutation (SNP) | VAF 18/268 reads (7%) | catalogued as COSV59593655; called by muse, mutect2
- GUCY1A1 | c.1009G>A p.G337R | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.127); catalogued as rs748904659, COSV56648752, COSV99638479; called by muse, mutect2, varscan2
- H2AC20 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 41/145 reads (28%) | catalogued as COSV100480144; called by muse, mutect2, varscan2
- H2BC8 | c.197T>C p.F66S | Missense Mutation (SNP) | VAF 98/269 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99773364; called by muse, mutect2, varscan2
- HAUS8 | c.1135del p.A379Lfs*51 | Frame Shift Del (DEL) | VAF 24/155 reads (15%) | catalogued as COSV99505173; called by mutect2, pindel, varscan2
- HELZ | c.2126A>G p.D709G | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100699015; called by muse, mutect2, varscan2
- HERC1 | c.6766A>C p.K2256Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.11); catalogued as COSV101496850; called by muse, mutect2, varscan2
- HERC1 | c.2534C>T p.T845I | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV101496851; called by muse, mutect2, varscan2
- HIC2 | c.1670G>T p.G557V | Missense Mutation (SNP) | VAF 56/103 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV101335626; called by muse, mutect2, varscan2
- HIP1 | c.379A>G p.M127V | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV100418102; called by muse, mutect2, varscan2
- HOXA6 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 60/320 reads (19%) | catalogued as COSV99762475; called by muse, mutect2, varscan2
- HS3ST2 | c.620C>A p.P207H | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1337948432, COSV99758512; called by muse, mutect2, varscan2
- HSPBAP1 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 57/409 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV99659244; called by muse, mutect2, varscan2
- HTR1E | c.716C>T p.T239I | Missense Mutation (SNP) | VAF 74/179 reads (41%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.53); catalogued as COSV100541267; called by muse, mutect2, varscan2
- HTR5A | c.211T>G p.F71V | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99839940; called by muse, mutect2, varscan2
- IARS1 | c.178C>A p.L60I | Missense Mutation (SNP) | VAF 35/51 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100986882, COSV65115288; called by muse, mutect2, varscan2
- IBA57 | c.1068G>T p.K356N | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV100812794; called by muse, mutect2, varscan2
- IGF2R | c.1156A>T p.K386* | Nonsense Mutation (SNP) | VAF 15/65 reads (23%) | catalogued as COSV100808069; called by muse, mutect2, varscan2
- IGHV3-72 | c.140C>T p.T47I | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.236); catalogued as rs548318617, COSV101455363; called by muse, mutect2, varscan2
- IGSF9B | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV58072877; called by muse, mutect2, varscan2
- IL1RAPL1 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 38/40 reads (95%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs778199033, COSV56261367; called by muse, mutect2, varscan2
- IMPG1 | c.435C>A p.S145R | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100886620; called by muse, mutect2, varscan2
- IRF2BPL | c.2132G>A p.G711E | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.69); catalogued as COSV99468445; called by muse, mutect2, varscan2
- IRX1 | c.341C>A p.A114E | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.123); catalogued as COSV100116749, COSV57358467, COSV57362662; called by muse, mutect2
- ITGA6 | c.146C>G p.A49G | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99906004; called by muse, mutect2, varscan2
- KALRN | c.894G>A p.M298I | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); catalogued as COSV99566977; called by muse, mutect2, varscan2
- KARS1 | c.1024A>G p.M342V | Missense Mutation (SNP) | VAF 53/192 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as rs1464972357, COSV100094473; called by muse, mutect2, varscan2
- KCNA2 | c.1164G>C p.K388N | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100316103; called by muse, mutect2, varscan2
- KCNIP4 | c.242A>C p.K81T | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.414); catalogued as COSV100749709; called by muse, mutect2, varscan2
- KCNQ3 | c.2066A>T p.E689V | Missense Mutation (SNP) | VAF 42/243 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.446); catalogued as COSV101196379; called by muse, mutect2, varscan2
- KCNQ4 | c.1588G>T p.V530L | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as COSV100714406; called by muse, mutect2, varscan2
- KIF21B | c.1404C>T p.G468= | Splice Region (SNP) | VAF 16/85 reads (19%) | catalogued as COSV59769282; called by muse, mutect2, varscan2
- KIF3C | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99267858; called by muse, mutect2, varscan2
- KMT2E | c.5354A>C p.H1785P | Missense Mutation (SNP) | VAF 49/497 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as COSV99996902; called by muse, mutect2, varscan2
- LAMA3 | c.2117G>A p.R706Q | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs775084106, COSV58062420; called by muse, mutect2, varscan2
- LAMA3 | c.3310C>T p.P1104S | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV58084095; called by muse, mutect2, varscan2
- LAMA4 | c.1428G>T p.E476D (on ENST00000230538 / NM_001105206.3; = p.E469D on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.065); catalogued as COSV100039285; called by muse, mutect2, varscan2
- LAMC3 | c.738C>A p.D246E | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100736068, COSV63088511; called by muse, mutect2, varscan2
- LCE2C | c.145G>T p.G49C | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.685); catalogued as COSV100909471; called by muse, mutect2, varscan2
- LDB2 | c.463A>T p.I155F | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100454662; called by muse, mutect2, varscan2
- LILRA1 | c.1016G>T p.G339V | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99252107; called by muse, mutect2, varscan2
- LIN7A | c.184T>C p.C62R | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1282463099, COSV99692627; called by muse, mutect2, varscan2
- LMNTD2 | c.578T>A p.M193K | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV99530770; called by muse, mutect2, varscan2
- LMNTD2 | c.372G>C p.L124F | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV99530771; called by muse, mutect2, varscan2
- LPA | c.5659C>T p.H1887Y | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100307926; called by muse, mutect2
- LPCAT1 | c.468G>T p.E156D | Missense Mutation (SNP) | VAF 16/267 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV99359166; called by muse, mutect2
- LRP1B | c.5907G>C p.W1969C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101260119, COSV67252587; called by muse, mutect2, varscan2
- LRRC66 | c.907A>T p.T303S | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as COSV100603076; called by muse, mutect2, varscan2
- LRRC66 | c.635C>G p.P212R | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100603077; called by muse, mutect2, varscan2
- LRRC71 | c.1551G>C p.W517C | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100168551, COSV100168906; called by muse, mutect2, varscan2
- LRRTM1 | c.1219G>T p.E407* | Nonsense Mutation (SNP) | VAF 48/108 reads (44%) | catalogued as COSV99703035; called by muse, mutect2, varscan2
- LTN1 | c.2474A>T p.D825V | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100798162; called by muse, mutect2, varscan2
- MAN1A1 | c.243G>T p.Q81H | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.547); catalogued as COSV100870422; called by muse, mutect2, varscan2
- MAP3K1 | c.2089C>T p.R697C | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753037944, COSV68126066; called by muse, mutect2, varscan2
- MASP1 | c.473A>G p.H158R | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99397613; called by muse, mutect2, varscan2
- MATN2 | c.2870G>T p.*957Lext*9 | Nonstop Mutation (SNP) | VAF 3/40 reads (8%) | catalogued as COSV99647039; called by muse, mutect2
- MATN4 | c.1312T>C p.F438L (on ENST00000372754; = p.F397L on NM_003833.4) | Missense Mutation (SNP) | VAF 23/81 reads (28%) | PolyPhen probably damaging (0.997); catalogued as rs752310758, COSV100637158; called by muse, mutect2, varscan2
- MDGA2 | c.2272A>G p.K758E (on ENST00000399232 / NM_001113498.2; = p.K460E on NM_182830.4) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as COSV100638256; called by muse, mutect2, varscan2
- MED26 | c.775A>T p.T259S | Missense Mutation (SNP) | VAF 47/73 reads (64%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV99660149; called by muse, mutect2, varscan2
- MED26 | c.774G>T p.E258D | Missense Mutation (SNP) | VAF 48/74 reads (65%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV99660152; called by muse, mutect2, varscan2
- MMP16 | c.1785C>A p.H595Q | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as COSV99690129; called by muse, mutect2, varscan2
- MMP27 | c.578C>A p.T193N | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV99498652; called by muse, mutect2, varscan2
- MOAP1 | c.435G>T p.M145I | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.14); catalogued as COSV99365780; called by muse, mutect2, varscan2
- MON1A | c.1429G>T p.A477S | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV56560918, COSV99616981; called by muse, mutect2, varscan2
- MS4A13 | c.406C>T p.R136* | Nonsense Mutation (SNP) | VAF 9/55 reads (16%) | catalogued as rs537359668, COSV65445543; called by muse, mutect2
- MSANTD2 | c.1280A>C p.Y427S (on ENST00000374979 / NM_001308027.2; = p.Y375S on NM_024631.4) | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99515916; called by muse, mutect2, varscan2
- MUC16 | c.40804G>A p.V13602M | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.976); catalogued as rs1156951777, COSV101110072; called by muse, mutect2, varscan2
- MUC16 | c.5884A>G p.M1962V | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV67457930; called by muse, mutect2, varscan2
- MUC17 | c.2498C>A p.S833Y | Missense Mutation (SNP) | VAF 106/1179 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV100074841; called by muse, mutect2
- MUC17 | c.8209G>T p.E2737* | Nonsense Mutation (SNP) | VAF 34/1171 reads (3%) | catalogued as COSV60289934; called by muse, mutect2
- MUC17 | c.13247C>A p.S4416Y | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as COSV100074844; called by muse, mutect2
- MUC5B | c.15121C>A p.P5041T | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); catalogued as COSV101500699; called by muse, mutect2, varscan2
- MYH6 | c.5773A>G p.K1925E | Missense Mutation (SNP) | VAF 73/141 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV100198181; called by muse, mutect2, varscan2
- MYH6 | c.1855G>A p.A619T | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.203); catalogued as COSV100676941; called by muse, mutect2, varscan2
- MYO7A | c.728G>C p.C243S | Missense Mutation (SNP) | VAF 30/213 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV101289257; called by muse, mutect2, varscan2
- MYOT | c.946T>C p.S316P | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV99525096; called by muse, mutect2, varscan2
- MYT1L | c.2406G>A p.M802I | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV101221346; called by muse, mutect2, varscan2
- NCAPD3 | c.1619G>T p.R540I | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV101599377, COSV101599398, COSV104440259; called by muse, mutect2, varscan2
- NCOR1 | c.6241T>A p.F2081I | Missense Mutation (SNP) | VAF 58/98 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV99251804; called by muse, mutect2, varscan2
- NDUFAF4 | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100294133, COSV60214368; called by muse, varscan2
- NDUFS6 | c.224A>G p.Q75R | Missense Mutation (SNP) | VAF 26/466 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.704); catalogued as COSV99929131; called by muse, mutect2
- NDUFS7 | c.439G>T p.V147L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (1); catalogued as COSV99282986; called by muse, mutect2, varscan2
- NELL1 | c.334A>C p.S112R | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.122); catalogued as rs1310142895, COSV100124483; called by muse, mutect2, varscan2
- NFX1 | c.97G>T p.G33W | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV100582406; called by muse, mutect2, varscan2
- NHS | c.4228G>T p.V1410L | Missense Mutation (SNP) | VAF 34/46 reads (74%) | SIFT deleterious (0.04); PolyPhen benign (0.234); catalogued as COSV101196934; called by muse, mutect2, varscan2
- NLRP3 | c.1115C>G p.S372C | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100276559, COSV60220608; called by muse, mutect2, varscan2
- NR1I3 | c.975C>G p.S325R (on ENST00000367982 / NM_001077480.3; = p.S321R on NM_005122.5) | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100915864; called by muse, mutect2, varscan2
- NSUN3 | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100113445; called by muse, mutect2, varscan2
- NXPH1 | c.767G>T p.C256F | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101339790; called by muse, mutect2, varscan2
- NYAP2 | c.1589G>T p.S530I | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99798256; called by muse, mutect2
- ODF2 | c.2228A>G p.K743R (on ENST00000434106 / NM_153433.2; = p.K719R on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.206); catalogued as COSV100654947; called by muse, mutect2, varscan2
- OR1D5 | c.714C>A p.F238L | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV101643443; called by muse, mutect2, varscan2
- OR1L3 | c.661A>G p.I221V | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1310187804, COSV100506302; called by muse, mutect2, varscan2
- OR2G2 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.803); catalogued as rs1288490713, COSV100189957; called by muse, mutect2, varscan2
- OR4C13 | c.897G>C p.L299F | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.111); catalogued as COSV101634230, COSV73648806; called by muse, mutect2, varscan2
- OR4C15 | c.580T>A p.C194S (on ENST00000314644; = p.C140S on NM_001001920.2) | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV100116036; called by muse, mutect2, varscan2
- OR51S1 | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV100437581, COSV59058389; called by muse, mutect2, varscan2
- OR5B12 | c.827A>G p.Y276C | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as COSV100222536; called by muse, mutect2, varscan2
- OR5B21 | c.236C>G p.T79R | Missense Mutation (SNP) | VAF 54/96 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.18); catalogued as COSV100835182, COSV64482359; called by muse, mutect2, varscan2
- PAGE3 | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV100892016; called by muse, mutect2, varscan2
- PAH | c.193A>C p.I65L | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.758); catalogued as CM010949, COSV100188387; called by muse, mutect2, varscan2
- PAPPA2 | c.1273A>T p.T425S | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.012); catalogued as COSV100867084; called by muse, mutect2, varscan2
- PAPPA2 | c.4057T>A p.S1353T | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.347); catalogued as COSV100868549; called by muse, mutect2, varscan2
- PARD6G | c.66G>T p.K22N | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.364); catalogued as COSV100783462; called by muse, mutect2, varscan2
- PARP2 | c.1180C>A p.H394N | Missense Mutation (SNP) | VAF 9/188 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99163032; called by muse, mutect2
- PCDH15 | c.643G>C p.V215L | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.854); catalogued as COSV100226654; called by muse, mutect2, varscan2
- PCDH15 | c.475-1G>A p.X159_splice | Splice Site (SNP) | VAF 29/74 reads (39%) | catalogued as COSV100219125, COSV57354800; called by muse, mutect2, varscan2
- PCDH17 | c.2620C>G p.Q874E | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.175); catalogued as COSV100931948; called by muse, mutect2, varscan2
- PCDHB8 | c.295C>A p.H99N | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.018); catalogued as COSV99176469, COSV99177302; called by muse, mutect2, varscan2
- PCSK5 | c.4153G>A p.D1385N | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.084); catalogued as rs781310006, COSV70450296; called by muse, mutect2, varscan2
- PDZD2 | c.6596G>C p.R2199T | Missense Mutation (SNP) | VAF 65/978 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV99226479; called by muse, mutect2
- PDZD4 | c.365G>C p.R122P | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99381616; called by muse, mutect2, varscan2
- PEG3 | c.3742A>G p.R1248G | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.057); catalogued as COSV99690193; called by muse, mutect2, varscan2
- PFKFB3 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 17/88 reads (19%) | PolyPhen benign (0.048); catalogued as rs775606147, COSV100432325; called by muse, mutect2, varscan2
- PHKA1 | c.1532A>G p.Y511C | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59812369; called by muse, mutect2, varscan2
- PIGV | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1168553787, COSV50293331; called by muse, mutect2
- PINK1 | c.1318G>A p.G440R | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100387412, COSV58632666; called by muse, mutect2, varscan2
- PKHD1 | c.9470C>G p.A3157G | Missense Mutation (SNP) | VAF 47/397 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100584381; called by muse, mutect2, varscan2
- PKHD1L1 | c.4333C>G p.P1445A | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.093); catalogued as COSV101006745; called by muse, mutect2, varscan2
- PLCB4 | c.1932C>G p.C644W | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99596767; called by muse, mutect2, varscan2
- PLEKHA3 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 61/133 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV99317869; called by muse, mutect2, varscan2
- PLXDC1 | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100195778; called by muse, mutect2, varscan2
- PMF1 | c.249G>T p.Q83H | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV100196385; called by muse, mutect2, varscan2
- PPAN | c.1411A>G p.R471G | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as COSV99461757; called by muse, mutect2
- PPWD1 | c.993G>A p.M331I | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV99731554; called by muse, mutect2, varscan2
- PRDM14 | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 28/197 reads (14%) | catalogued as COSV52571722, COSV99400478; called by muse, mutect2, varscan2
- PRKAG2 | c.774T>G p.S258R | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV99835896; called by muse, mutect2, varscan2
- PRKDC | c.8860C>G p.Q2954E | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV100042526; called by muse, mutect2
- PRKG1 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV64824978; called by muse, mutect2, varscan2
- PRKG1 | c.485A>T p.K162M | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as COSV64805010; called by mutect2, varscan2
- PRPF8 | c.1255C>G p.R419G | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.92); catalogued as COSV100517841; called by muse, mutect2, varscan2
- PRPS1L1 | c.949C>G p.P317A | Missense Mutation (SNP) | VAF 45/241 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV101552953, COSV101552962; called by muse, mutect2, varscan2
- PSG8 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 38/255 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.274); catalogued as rs769407964, COSV100126120; called by muse, mutect2, varscan2
- PTPRK | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.098); catalogued as COSV100951494; called by muse, mutect2, varscan2
- PUM1 | c.757G>C p.G253R | Missense Mutation (SNP) | VAF 38/251 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.101); catalogued as COSV99928853; called by muse, mutect2, varscan2
- PWWP3A | c.533A>G p.K178R (on ENST00000627377; = p.K177R on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV100262237; called by muse, mutect2
- QRFPR | c.1048T>C p.C350R | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as rs989393654, COSV100543938; called by muse, mutect2, varscan2
- RAD54L2 | c.4154C>G p.P1385R | Missense Mutation (SNP) | VAF 86/168 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.403); catalogued as COSV99621768; called by muse, mutect2, varscan2
- RALGAPA2 | c.3162C>G p.I1054M | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV52512806, COSV99174843; called by muse, mutect2, varscan2
- RCBTB1 | c.1342A>G p.T448A | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT deleterious (0.05); PolyPhen benign (0.159); catalogued as COSV99319696; called by muse, mutect2, varscan2
- RECK | c.1600G>A p.D534N | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); catalogued as COSV100937624; called by muse, mutect2, varscan2
- RGS22 | c.1035C>G p.F345L | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.368); catalogued as COSV100693710; called by muse, mutect2
- RGS3 | c.858G>A p.M286I (on ENST00000350696 / NM_001282923.2; = p.M174I on NM_017790.4) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV100465851; called by muse, mutect2, varscan2
- RGS7 | c.782A>G p.Q261R | Missense Mutation (SNP) | VAF 45/74 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.392); catalogued as COSV100467715, COSV100470519; called by muse, mutect2, varscan2
- RIMS1 | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs926873828, COSV99330020; called by muse, mutect2, varscan2
- RIPPLY2 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD1511080, COSV100859540; called by muse, mutect2, varscan2
- RNASE3 | c.145C>T p.R49* | Nonsense Mutation (SNP) | VAF 35/121 reads (29%) | catalogued as COSV100484210, COSV100484283, COSV58959694; called by muse, mutect2, varscan2
- RNF139 | c.1318G>A p.V440I | Missense Mutation (SNP) | VAF 28/372 reads (8%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.644); catalogued as COSV99413683; called by muse, mutect2
- RPS6KB2 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 40/193 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57050726; called by muse, mutect2, varscan2
- RYR2 | c.14860G>T p.A4954S | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV100772528, COSV63710742; called by muse, mutect2, varscan2
- SDCBP2 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV100378370; called by muse, mutect2, varscan2
- SDR16C5 | c.665G>T p.C222F | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV100374132; called by muse, mutect2, varscan2
- SEPTIN10 | c.347A>T p.N116I | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV100454306; called by muse, mutect2, varscan2
- SGCE | c.274G>A p.V92I (on ENST00000647096; = p.V56I on NM_003919.3) | Missense Mutation (SNP) | VAF 215/308 reads (70%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99722885; called by muse, mutect2, varscan2
- SI | c.1255G>T p.G419* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as COSV100016891, COSV52299629; called by muse, mutect2
- SIPA1L2 | c.4978C>G p.Q1660E | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99479494; called by muse, mutect2, varscan2
- SLC12A6 | c.2663T>G p.L888R (on ENST00000354181 / NM_001365088.1; = p.L837R on NM_005135.2) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.197); catalogued as COSV99273257; called by muse, mutect2, varscan2
- SLC16A5 | c.363C>A p.S121R | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100317221; called by muse, mutect2
- SLC25A36 | c.845G>A p.R282H (on ENST00000324194 / NM_001104647.3; = p.R281H on NM_018155.3) | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as rs756039412, COSV60782550, COSV60782866; called by muse, mutect2, varscan2
- SLC29A4 | c.1249C>A p.L417M | Missense Mutation (SNP) | VAF 78/182 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.872); catalogued as COSV51877018, COSV99786922; called by muse, mutect2, varscan2
- SLC39A3 | c.589G>T p.V197L | Missense Mutation (SNP) | VAF 12/195 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV99514297; called by muse, mutect2
- SMG8 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); catalogued as rs1330337025, COSV99959035; called by muse, mutect2, varscan2
- SMPD4 | c.2275G>T p.A759S (on ENST00000409031 / NM_017951.4; = p.A730S on NM_017751.4) | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.521); catalogued as COSV100302729; called by muse, mutect2, varscan2
- SNTA1 | c.1325G>C p.R442P | Missense Mutation (SNP) | VAF 70/184 reads (38%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.615); catalogued as COSV54129870, COSV99458918; called by muse, mutect2, varscan2
- SNTG1 | c.514A>T p.S172C | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99385769; called by muse, mutect2, varscan2
- SNTG2 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 77/173 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100424503; called by muse, mutect2, varscan2
- SNX16 | c.1031A>T p.D344V | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.147); catalogued as COSV100629694; called by muse, mutect2, varscan2
- SORCS1 | c.1760G>T p.S587I | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV99549772; called by muse, mutect2, varscan2
- SOX11 | c.101T>C p.L34P | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.056); catalogued as COSV100431370; called by muse, mutect2, varscan2
- SPECC1L | c.3256T>C p.S1086P | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as COSV100063148; called by muse, mutect2, varscan2
- ST18 | c.8C>G p.A3G | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV99390879; called by muse, mutect2, varscan2
- STAC | c.615C>A p.F205L | Missense Mutation (SNP) | VAF 69/297 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV56210826, COSV99830682; called by muse, mutect2, varscan2
- STXBP5 | c.3368C>G p.A1123G (on ENST00000321680 / NM_001127715.2; = p.A1087G on NM_139244.4) | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV51659028, COSV99470860; called by muse, mutect2, varscan2
- SUSD5 | c.127C>A p.L43M | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100535323, COSV58879143; called by muse, mutect2, varscan2
- SYCP1 | c.1494G>C p.E498D | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV101051168; called by muse, varscan2
- SYNE1 | c.20030C>T p.A6677V (on ENST00000367255 / NM_182961.4; = p.A6606V on NM_033071.3) | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99576368; called by muse, mutect2
- SYNE2 | c.3644A>C p.E1215A | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100648396; called by muse, mutect2, varscan2
- TATDN2 | c.1712A>G p.Y571C | Missense Mutation (SNP) | VAF 74/169 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99813711; called by muse, mutect2, varscan2
- TCF7L2 | c.1105G>A p.V369I (on ENST00000355995 / NM_001367943.1; = p.V346I on NM_030756.5) | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.528); catalogued as COSV53342492; called by muse, mutect2, varscan2
- TDRD6 | c.4330G>A p.E1444K | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs139292044; called by muse, mutect2, varscan2
- TENM4 | c.6572G>A p.R2191H | Missense Mutation (SNP) | VAF 70/124 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs761633956, COSV99578518; called by muse, mutect2, varscan2
- TGM1 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV99253200; called by muse, mutect2, varscan2
- THSD7A | c.2938G>A p.E980K | Missense Mutation (SNP) | VAF 43/202 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV101448871; called by muse, mutect2, varscan2
- THSD7B | c.3650G>T p.S1217I (on ENST00000272643; = p.S1215I on NM_001316349.2) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99757477; called by muse, mutect2, varscan2
- TIA1 | c.64C>G p.L22V | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.842); catalogued as rs1302550584, COSV99248956; called by muse, mutect2, varscan2
- TIMD4 | c.193A>T p.K65* | Nonsense Mutation (SNP) | VAF 18/63 reads (29%) | catalogued as COSV99192866; called by muse, mutect2, varscan2
- TJP2 | c.2044C>G p.R682G | Missense Mutation (SNP) | VAF 113/198 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55264329, COSV99601760; called by muse, mutect2, varscan2
- TLCD1 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs377224480; called by muse, mutect2, varscan2
- TMC2 | c.2182G>T p.G728W | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100727943; called by muse, mutect2, varscan2
- TMCO5A | c.215T>A p.M72K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.069); catalogued as COSV100148692; called by muse, mutect2, varscan2
- TNFRSF25 | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100557105; called by muse, mutect2, varscan2
- TNK1 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV100294969; called by muse, mutect2, varscan2
- TOP2A | c.1932A>C p.E644D | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV101396369; called by muse, mutect2
- TRAT1 | c.177C>A p.D59E | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.914); catalogued as COSV99849526; called by muse, mutect2, varscan2
- TRPV5 | c.1789-2A>G p.X597_splice | Splice Site (SNP) | VAF 4/25 reads (16%) | catalogued as COSV99520966; called by muse, mutect2
- TSPEAR | c.271G>A p.V91I | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as rs1555921926, COSV59972033; ClinVar: likely benign; called by muse, mutect2
- TSPOAP1 | c.2627C>T p.A876V | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs766215697, COSV99272490; called by muse, mutect2, varscan2
- TSPYL5 | c.59G>T p.R20L | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as rs1172836039, COSV59070908, COSV59071533; called by muse, mutect2, varscan2
- TTC13 | c.2468G>A p.S823N | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.197); catalogued as COSV100793001; called by muse, mutect2, varscan2
- TTC13 | c.1783A>T p.R595* | Nonsense Mutation (SNP) | VAF 28/86 reads (33%) | catalogued as COSV100793003; called by muse, varscan2
- TTC3 | c.2078A>G p.K693R | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100695977; called by muse, mutect2, varscan2
- TTLL4 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 75/157 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs758811791, COSV51436432; called by muse, mutect2, varscan2
- TTN | c.96886C>G p.H32296D (on ENST00000591111; = p.H24872D on NM_003319.4) | Missense Mutation (SNP) | VAF 30/52 reads (58%) | PolyPhen benign (0.405); catalogued as COSV100627131; called by muse, mutect2, varscan2
- TXNRD1 | c.328A>G p.T110A (on ENST00000525566 / NM_001093771.3; = p.T12A on NM_003330.4) | Missense Mutation (SNP) | VAF 9/236 reads (4%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV100723558; called by muse, mutect2
- UHRF1 | c.1759C>T p.P587S (on ENST00000612630 / NM_001290050.1; = p.P600S on NM_013282.4) | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.323); catalogued as COSV99503707; called by muse, mutect2
- USH2A | c.1421C>A p.P474Q | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV100241510; called by muse, mutect2, varscan2
- VPS54 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV99707683, COSV99708656; called by muse, mutect2, varscan2
- VWA8 | c.545A>G p.E182G | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99864965; called by muse, mutect2
- WDR48 | c.1961T>C p.L654P | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100073301; called by muse, mutect2, varscan2
- WDR75 | c.1884A>C p.K628N | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.093); catalogued as COSV100134431; called by muse, mutect2, varscan2
- WNK4 | c.1583G>C p.R528T | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as COSV99891333; called by muse, mutect2, varscan2
- WNT3A | c.704A>G p.Y235C | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99470106; called by muse, mutect2, varscan2
- YPEL5 | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.308); catalogued as COSV99745322; called by muse, mutect2, varscan2
- YY1AP1 | c.1720C>T p.R574W (on ENST00000295566 / NM_139118.2; = p.R517W on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.963); catalogued as rs752169560, COSV99804597; called by muse, mutect2, varscan2
- ZBED8 | c.853A>G p.T285A | Missense Mutation (SNP) | VAF 60/98 reads (61%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs373348957; called by muse, mutect2, varscan2
- ZBED9 | c.2845G>T p.A949S | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.36); catalogued as COSV101509371; called by muse, mutect2, varscan2
- ZBTB24 | c.1558G>T p.D520Y | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as COSV100018712; called by muse, mutect2, varscan2
- ZMYM6 | c.1193C>A p.P398H | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as COSV100593323; called by muse, mutect2
- ZNF267 | c.1985G>A p.C662Y | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138496836; called by muse, mutect2, varscan2
- ZNF3 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.111); catalogued as COSV99447386; called by muse, mutect2
- ZNF33A | c.727G>A p.E243K (on ENST00000458705 / NM_006974.3; = p.E244K on NM_006954.2) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.321); catalogued as rs1228209536, COSV100276160; called by muse, mutect2, varscan2
- ZNF365 | c.1130C>A p.P377Q | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV101237984; called by muse, mutect2, varscan2
- ZNF506 | c.293T>A p.V98E | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV101475660; called by muse, mutect2, varscan2
- ZNF638 | c.5290G>C p.D1764H | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100039780; called by muse, mutect2, varscan2
- ZNF676 | c.562C>A p.L188I (on ENST00000650058; = p.L156I on NM_001001411.3) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.792); catalogued as COSV68093536; called by muse, mutect2, varscan2
- ZNF776 | c.1176G>T p.K392N | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.381); catalogued as COSV100414332; called by muse, mutect2, varscan2
- ZNF804A | c.3373C>G p.L1125V | Missense Mutation (SNP) | VAF 57/123 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as COSV100169880, COSV100170308; called by muse, mutect2, varscan2
- ZNF831 | c.532G>A p.G178S | Missense Mutation (SNP) | VAF 47/243 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs763900056, COSV64042539; called by muse, mutect2, varscan2
- ZYX | c.1307G>C p.C436S | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99314606; called by muse, mutect2, varscan2
- ANKRD24 | c.2765T>A p.L922Q | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.144); called by muse, mutect2
- ARHGAP35 | c.4203_4212del p.W1401* | Frame Shift Del (DEL) | VAF 91/285 reads (32%) | called by mutect2, pindel, varscan2
- ATM | c.4573dup p.I1525Nfs*6 | Frame Shift Ins (INS) | VAF 26/149 reads (17%) | called by mutect2, pindel, varscan2
- COPS3 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 7/182 reads (4%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2
- EPHA5 | c.701dup p.S235Ffs*11 | Frame Shift Ins (INS) | VAF 11/40 reads (28%) | called by mutect2, pindel, varscan2
- IGKV1-12 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 31/332 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- IGKV1D-8 | c.268G>T p.G90W | Missense Mutation (SNP) | VAF 53/289 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- IGKV3D-15 | c.31C>A p.L11M | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGLV2-8 | c.141C>G p.D47E | Missense Mutation (SNP) | VAF 196/503 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- OR1S1 | c.276del p.M94Cfs*3 | Frame Shift Del (DEL) | VAF 64/352 reads (18%) | called by mutect2, varscan2
- PCDH7 | c.2326G>C p.G776R | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB2 | c.2110C>T p.L704F | Missense Mutation (SNP) | VAF 13/294 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.417); called by muse, mutect2
- PCDHGB5 | c.240G>T p.E80D | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PDZRN4 | c.1592del p.K531Sfs*25 (on ENST00000402685 / NM_001164595.2; = p.K273Sfs*25 on NM_013377.4) | Frame Shift Del (DEL) | VAF 18/36 reads (50%) | called by mutect2, pindel, varscan2
- PUM2 | c.2898dup p.A967Cfs*5 | Frame Shift Ins (INS) | VAF 13/88 reads (15%) | called by mutect2, pindel, varscan2
- RASGRP3 | c.608del p.K203Sfs*5 | Frame Shift Del (DEL) | VAF 39/197 reads (20%) | called by mutect2, pindel, varscan2
- SH3TC1 | c.2226del p.G743Afs*3 | Frame Shift Del (DEL) | VAF 15/91 reads (16%) | called by mutect2, pindel, varscan2
- SP140 | c.732_738del p.Y244* | Frame Shift Del (DEL) | VAF 15/36 reads (42%) | called by mutect2, pindel, varscan2
- SYT16 | c.311del p.N104Ifs*63 | Frame Shift Del (DEL) | VAF 29/116 reads (25%) | called by mutect2, pindel, varscan2
- TSPAN3 | c.102_143del p.F35_V48del | In Frame Del (DEL) | VAF 10/136 reads (7%) | called by mutect2, pindel
- USP24 | c.648del p.E217Rfs*3 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel, varscan2
- ZIC3 | c.986del p.P329Hfs*79 | Frame Shift Del (DEL) | VAF 47/105 reads (45%) | called by mutect2, pindel, varscan2
- ZNF485 | c.404delinsTT p.C135Ffs*13 | Frame Shift Ins (INS) | VAF 12/64 reads (19%) | called by mutect2*, pindel, varscan2*
- ABLIM2 | c.1278C>T p.G426= (on ENST00000341937 / NM_001130084.2; = p.G459= on NM_001130083.2) | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as rs41266515, COSV99589269; called by muse, mutect2, varscan2
- ACHE | c.954C>T p.H318= | Silent (SNP) | VAF 17/157 reads (11%) | catalogued as rs550722884, COSV53815312; called by muse, mutect2, varscan2
- ACSF2 | c.1515C>T p.I505= | Silent (SNP) | VAF 83/207 reads (40%) | catalogued as rs891864595, COSV99366313; called by muse, mutect2, varscan2
- ACTN2 | c.157A>C p.R53= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV100856963; called by muse, mutect2, varscan2
- AFF1 | c.2334G>T p.G778= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV100321010, COSV57118574; called by muse, mutect2, varscan2
- AHNAK2 | c.7647G>A p.V2549= | Silent (SNP) | VAF 86/246 reads (35%) | catalogued as COSV60906422; called by muse, mutect2, varscan2
- AKR7A2 | c.234C>T p.S78= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs1345217237, COSV99352162; called by muse, mutect2
- AMER2 | c.1281C>T p.S427= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV100766368; called by muse, mutect2, varscan2
- AMY2A | c.390T>C p.C130= | Silent (SNP) | VAF 22/243 reads (9%) | catalogued as COSV101340671; called by muse, mutect2, varscan2
- ANKRD30A | c.1389C>A p.A463= (on ENST00000611781; = p.A407= on NM_052997.2) | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV100654327; called by muse, mutect2, varscan2
- ARHGAP28 | c.858G>A p.L286= (on ENST00000383472 / NM_001366230.1; = p.L127= on NM_001010000.3) | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as COSV51636034, COSV99151354; called by muse, mutect2, varscan2
- ARHGEF3 | c.138G>A p.T46= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as rs777872211, COSV56326648; called by muse, mutect2, varscan2
- ARMC12 | c.888C>A p.A296= (on ENST00000373866 / NM_001286574.2; = p.A323= on NM_145028.5) | Silent (SNP) | VAF 52/177 reads (29%) | catalogued as COSV99849582; called by muse, mutect2, varscan2
- ATP10A | c.3939G>A p.K1313= | Silent (SNP) | VAF 8/167 reads (5%) | catalogued as rs892067754, COSV100791485, COSV63517464; called by muse, mutect2
- BBS2 | c.1875G>T p.L625= | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as COSV99802757; called by muse, mutect2, varscan2
- BBX | c.2445G>T p.T815= (on ENST00000325805 / NM_001142568.3; = p.T785= on NM_020235.7) | Silent (SNP) | VAF 39/115 reads (34%) | catalogued as rs150447882, COSV100362197; called by muse, mutect2, varscan2
- C16orf71 | c.288G>A p.V96= | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as COSV100173091; called by muse, mutect2, varscan2
- CASKIN2 | c.3117C>A p.P1039= | Silent (SNP) | VAF 24/130 reads (18%) | catalogued as COSV100050858; called by muse, mutect2, varscan2
- CDH8 | c.1119A>G p.K373= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as COSV100183886; called by muse, mutect2, varscan2
- CHRNA7 | c.741C>T p.L247= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs770076529; called by mutect2, varscan2
- CNOT1 | c.6228G>A p.A2076= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as rs1037557295, COSV99801064; called by muse, mutect2, varscan2
- CNTN6 | c.609C>A p.A203= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV100611729; called by muse, mutect2, varscan2
- COL21A1 | c.273C>G p.L91= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV55156646, COSV99780013; called by muse, mutect2, varscan2
- COX10 | c.807G>T p.L269= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV99886999; called by muse, mutect2, varscan2
- CRACDL | c.321G>C p.R107= | Silent (SNP) | VAF 72/270 reads (27%) | catalogued as COSV101194134; called by muse, mutect2, varscan2
- CSMD2 | c.8022T>C p.S2674= | Silent (SNP) | VAF 34/104 reads (33%) | catalogued as COSV99594577; called by muse, mutect2, varscan2
- CUX2 | c.2292C>A p.P764= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV55645560, COSV99920607, COSV99920690; called by muse, mutect2, varscan2
- CYP1B1 | c.588G>T p.L196= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs745532244, COSV99572821; called by muse, varscan2
- CYP21A2 | c.1017C>T p.D339= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as COSV100926589; called by muse, mutect2, varscan2
- DCAF1 | c.2436C>T p.L812= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs568857340, COSV100244880; called by mutect2, varscan2
- DMXL1 | c.2139T>A p.V713= | Silent (SNP) | VAF 52/85 reads (61%) | catalogued as COSV100224847; called by muse, mutect2, varscan2
- DNAH10 | c.7231C>T p.L2411= (on ENST00000409039; = p.L2350= on NM_207437.3) | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV101292580; called by muse, mutect2, varscan2
- DNAH9 | c.9126G>A p.K3042= | Silent (SNP) | VAF 51/74 reads (69%) | catalogued as COSV52372743, COSV99307760; called by muse, mutect2, varscan2
- DYTN | c.270G>T p.L90= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV101510899; called by muse, mutect2, varscan2
- EML3 | c.457C>A p.R153= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs368147676; called by muse, mutect2
- FABP7 | c.156C>T p.I52= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV100738006; called by muse, mutect2, varscan2
- FAM47A | c.1576C>A p.R526= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as COSV100650044; called by muse, mutect2, varscan2
- FAM47A | c.1537C>A p.R513= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV100650045; called by muse, varscan2
- FAT4 | c.1587C>T p.S529= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs770456067, COSV67885457; called by muse, mutect2, varscan2
- FGF7 | c.42C>T p.L14= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV99983604; called by muse, mutect2, varscan2
- GALNT17 | c.1755C>T p.S585= | Silent (SNP) | VAF 29/133 reads (22%) | catalogued as COSV100355924; called by muse, mutect2, varscan2
- GDF15 | c.315C>A p.I105= | Silent (SNP) | VAF 52/91 reads (57%) | catalogued as COSV99416277; called by muse, mutect2, varscan2
- GLB1L | c.1068G>A p.Q356= | Silent (SNP) | VAF 51/108 reads (47%) | catalogued as COSV99850825; called by muse, mutect2, varscan2
- GP5 | c.858C>T p.F286= | Silent (SNP) | VAF 6/108 reads (6%) | catalogued as COSV59880220; called by muse, mutect2
- GPR27 | c.42G>A p.E14= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV99816641; called by muse, mutect2
- HCST | c.168T>A p.A56= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV99385723; called by muse, mutect2, varscan2
- HEY2 | c.444G>A p.P148= | Silent (SNP) | VAF 48/120 reads (40%) | catalogued as rs766932885, COSV100856390, COSV100856427; called by muse, mutect2, varscan2
- HIRA | c.1515C>T p.D505= | Silent (SNP) | VAF 57/201 reads (28%) | catalogued as rs1017329385, COSV99600845; called by muse, mutect2, varscan2
- IDH3G | c.39G>T p.A13= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV99473394; called by muse, mutect2
- IL10RA | c.1368G>A p.K456= | Silent (SNP) | VAF 28/111 reads (25%) | catalogued as COSV99923237; called by muse, mutect2, varscan2
- ING5 | c.411A>G p.K137= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as COSV100546047; called by muse, mutect2, varscan2
- KAT6B | c.3768A>G p.L1256= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as rs371467644; called by muse, mutect2, varscan2
- KIAA1109 | c.7593C>G p.T2531= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as COSV99173851; called by muse, mutect2, varscan2
- LAIR1 | c.603C>T p.D201= | Silent (SNP) | VAF 25/101 reads (25%) | catalogued as rs752390066, COSV57306009; called by muse, mutect2, varscan2
- LPIN2 | c.1299C>A p.P433= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV99858906; called by muse, varscan2
- MACF1 | c.7701A>G p.K2567= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as COSV99246467; called by muse, mutect2, varscan2
- MACROD2 | c.333C>A p.P111= | Silent (SNP) | VAF 16/137 reads (12%) | catalogued as COSV99441899; called by muse, mutect2, varscan2
- MAGEC1 | c.1329C>A p.L443= | Silent (SNP) | VAF 55/130 reads (42%) | catalogued as COSV53570705, COSV99596410; called by muse, varscan2
- MAP2 | c.1425C>T p.T475= | Silent (SNP) | VAF 31/56 reads (55%) | catalogued as COSV52314299; called by muse, mutect2, varscan2
- MAP7D1 | c.2451C>G p.L817= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV100294765; called by muse, mutect2
- MARCHF6 | c.1548C>G p.L516= | Silent (SNP) | VAF 33/439 reads (8%) | catalogued as COSV99930117; called by muse, mutect2
- MED1 | c.336G>A p.V112= | Silent (SNP) | VAF 67/171 reads (39%) | catalogued as rs1308628497, COSV100328120; called by muse, mutect2, varscan2
- MIA2 | c.2118G>T p.V706= | Silent (SNP) | VAF 58/319 reads (18%) | catalogued as COSV99698137; called by muse, mutect2, varscan2
- MOGS | c.1137G>A p.K379= | Silent (SNP) | VAF 40/290 reads (14%) | catalogued as COSV99270754; called by muse, mutect2, varscan2
- MUC16 | c.40938G>T p.L13646= | Silent (SNP) | VAF 13/177 reads (7%) | catalogued as COSV101110071; called by muse, mutect2
- MUC16 | c.12951G>T p.V4317= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV101201340; called by muse, mutect2, varscan2
- MUC21 | c.1170C>A p.A390= | Silent (SNP) | VAF 167/513 reads (33%) | catalogued as COSV100888914; called by muse, mutect2, varscan2
- MXRA5 | c.885G>A p.E295= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV99478937; called by muse, mutect2, varscan2
- NLRP6 | c.1218G>A p.R406= | Silent (SNP) | VAF 41/165 reads (25%) | catalogued as COSV100381144; called by muse, mutect2, varscan2
- NR2F2 | c.450G>A p.Q150= | Silent (SNP) | VAF 44/150 reads (29%) | catalogued as rs1395412057, COSV101241158; called by muse, mutect2, varscan2
- NRAP | c.2709G>T p.T903= (on ENST00000359988 / NM_001322945.2; = p.T868= on NM_006175.4) | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as COSV100748577; called by muse, mutect2, varscan2
- NSD2 | c.1335A>G p.T445= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV100373830; called by muse, mutect2, varscan2
- OR2C3 | c.324G>T p.L108= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as COSV100825778, COSV63576338; called by muse, mutect2, varscan2
- OR8H2 | c.279C>T p.S93= | Silent (SNP) | VAF 88/408 reads (22%) | catalogued as rs1463792600, COSV100542464; called by muse, mutect2, varscan2
- OSR1 | c.525C>T p.F175= | Silent (SNP) | VAF 35/142 reads (25%) | catalogued as rs763783951, COSV55344981; called by muse, mutect2, varscan2
- OTOP3 | c.279C>T p.F93= | Silent (SNP) | VAF 46/112 reads (41%) | catalogued as COSV100173021; called by muse, mutect2, varscan2
- P2RX3 | c.130T>C p.L44= | Silent (SNP) | VAF 15/151 reads (10%) | catalogued as COSV99628889; called by muse, mutect2, varscan2
- PAH | c.192C>T p.H64= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV100188388; called by muse, mutect2, varscan2
- PDP1 | c.36C>A p.I12= | Silent (SNP) | VAF 18/128 reads (14%) | catalogued as COSV99892818; called by muse, mutect2, varscan2
- PPME1 | c.432G>T p.G144= | Silent (SNP) | VAF 40/171 reads (23%) | catalogued as COSV100076654; called by muse, mutect2, varscan2
- PRKACA | c.312C>A p.L104= | Silent (SNP) | VAF 19/168 reads (11%) | catalogued as COSV100432264, COSV58069223; called by muse, mutect2, varscan2
- PRKCA | c.60C>T p.F20= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as rs1432138923, COSV52583607; called by mutect2, varscan2
- PTPRH | c.1296C>T p.T432= | Silent (SNP) | VAF 36/89 reads (40%) | catalogued as COSV99671404; called by muse, mutect2, varscan2
- PXN | c.903G>A p.R301= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as rs757891043, COSV99936248; called by muse, mutect2, varscan2
- QSOX1 | c.726G>T p.R242= | Silent (SNP) | VAF 92/180 reads (51%) | catalogued as COSV100852945; called by muse, mutect2, varscan2
- R3HCC1L | c.426A>G p.P142= | Silent (SNP) | VAF 51/102 reads (50%) | catalogued as rs1339372924, COSV100107518; called by muse, mutect2, varscan2
- RAB40A | c.522G>A p.V174= | Silent (SNP) | VAF 21/32 reads (66%) | catalogued as COSV100421005; called by muse, mutect2, varscan2
- RFX1 | c.795G>T p.L265= | Silent (SNP) | VAF 85/212 reads (40%) | catalogued as COSV99586423; called by muse, mutect2, varscan2
- RGL1 | c.2103C>T p.V701= (on ENST00000360851 / NM_001297672.2; = p.V736= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV100487580, COSV58989568; called by muse, mutect2
- SARS2 | c.189C>T p.F63= | Silent (SNP) | VAF 79/171 reads (46%) | catalogued as rs763335001, COSV99671531; called by muse, mutect2, varscan2
- SEMA5A | c.2928G>T p.L976= | Silent (SNP) | VAF 18/390 reads (5%) | catalogued as COSV66799868; called by muse, mutect2
- SGK2 | c.864C>T p.L288= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100414818; called by muse, mutect2, varscan2
- SRPK1 | c.66C>T p.A22= | Silent (SNP) | VAF 20/228 reads (9%) | catalogued as rs374532523, COSV100644434; called by muse, mutect2
- SRSF4 | c.1359C>T p.N453= | Silent (SNP) | VAF 32/228 reads (14%) | catalogued as COSV100861430; called by muse, varscan2
- ST3GAL3 | c.237G>T p.L79= (on ENST00000361392 / NM_174964.4; = p.L64= on NM_006279.5) | Silent (SNP) | VAF 59/231 reads (26%) | catalogued as COSV99495961; called by muse, mutect2, varscan2
- STOML3 | c.348T>C p.D116= | Silent (SNP) | VAF 55/86 reads (64%) | catalogued as COSV101105391; called by muse, mutect2, varscan2
- TMEM196 | c.366C>A p.S122= | Silent (SNP) | VAF 16/108 reads (15%) | catalogued as COSV101337517; called by muse, mutect2, varscan2
- TNKS | c.696A>C p.V232= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as COSV100127771; called by muse, mutect2, varscan2
- TOPBP1 | c.2496C>A p.L832= | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as COSV99605775; called by muse, mutect2, varscan2
- TOX3 | c.1167C>A p.T389= | Silent (SNP) | VAF 128/277 reads (46%) | catalogued as COSV99568061; called by muse, mutect2, varscan2
- TRIM56 | c.1761C>T p.L587= | Silent (SNP) | VAF 37/543 reads (7%) | catalogued as rs780469410, COSV100047705; called by muse, mutect2
- TRPM6 | c.2808A>T p.T936= | Silent (SNP) | VAF 53/180 reads (29%) | catalogued as COSV100666906; called by muse, mutect2, varscan2
- UCP3 | c.156G>A p.T52= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs745356543, COSV58369502; called by muse, mutect2, varscan2
- WNT5B | c.342C>A p.T114= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs778345344, COSV100148818; called by muse, varscan2
- ZAN | c.3651C>G p.T1217= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV100770259; called by muse, mutect2, varscan2
- ZNF827 | c.2463G>T p.V821= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV101061697; called by muse, mutect2, varscan2
- ADGRE4P | n.1291G>C | RNA (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- DCHS2 | n.1546G>T | RNA (SNP) | VAF 17/50 reads (34%) | catalogued as COSV59719677; called by muse, mutect2, varscan2
- NCAPD2 | c.262+221A>T | Intron (SNP) | VAF 44/277 reads (16%) | catalogued as COSV100217416; called by muse, mutect2, varscan2
- OR2U1P | n.862T>A | RNA (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
- OR2W5 | n.476A>G | RNA (SNP) | VAF 16/85 reads (19%) | catalogued as rs761356687; called by muse, mutect2, varscan2
- OR8A1 | c.-34del | 5'UTR (DEL) | VAF 26/67 reads (39%) | called by mutect2, pindel, varscan2
- POMGNT1 | c.*347G>A | 3'UTR (SNP) | VAF 14/60 reads (23%) | catalogued as rs746679629, COSV100915784; called by mutect2, varscan2
- SNORD115-11 | n.11T>G | RNA (SNP) | VAF 44/374 reads (12%) | called by muse, mutect2, varscan2
